Gene-level copy-number profile of tumor specimen TCGA-77-7335-01A from TCGA case TCGA-77-7335, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 62.6 years (22,863 days).
Specimen TCGA-77-7335-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.7807fb8e-3110-4bef-808f-3f2be8a2ab25.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-7335-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/615234b0-f12a-4e7c-92b2-8a6716ea0ab4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,927; copy number 2: 43,018; copy number 3: 7,622; copy number 4: 507; copy number 7: 53; copy number 8: 688.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-7335-01A-11D-2041-01): tumor purity 0.41, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 741 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:158,962,235–198,222,513, 688 genes, copy number 8 (broad region; genes not listed).
- chr13:18,467,172–19,783,019, 53 genes, copy number 7 (within-gene range 1–7): ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P.

Autosomal genes at a single copy (total copy number 1): 6,487. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
